Gene-level copy-number profile of tumor specimen TCGA-12-1597-01B from TCGA case TCGA-12-1597, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.6 years (22,865 days).
Specimen TCGA-12-1597-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8e002c1f-5d5c-47f4-8c33-681cd2c2d3c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1597-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate.
https://portal.gdc.cancer.gov/files/aed5d720-b466-43a4-ab3e-a46488542038

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,094; copy number 3: 2,329; copy number 4: 45,565; copy number 5: 3,175; copy number 6: 6,064; copy number 7: 3; copy number 8: 1,467; copy number 20: 88; copy number 37: 6; copy number 39: 23; copy number 41: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 123 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,377,850–204,435,846, 1 gene, copy number 37 (within-gene range 4–37): AL606489.1.
- chr1:204,403,381–204,562,521, 5 genes, copy number 37: PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr4:51,843,000–56,328,625, 88 genes, copy number 20 (broad region; genes not listed).
- chr7:54,933,699–55,260,256, 6 genes, copy number 41: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr12:57,674,665–57,896,846, 23 genes, copy number 39: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
